Somatic mutation profile of tumor specimen HCM-CSHL-0162-C19-01A (aliquot HCM-CSHL-0162-C19-01A-11D-A786-36) from HCMI case HCM-CSHL-0162-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,776 days).
Specimen HCM-CSHL-0162-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f715fb93-f105-488c-88c1-12e889120336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0162-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0162-C19-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/112552db-d428-443d-a4cc-d710e69badc1

The open-access MAF lists 114 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, 3'UTR 7, Intron 6, Nonsense Mutation 4, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 90/344 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADAD2 | c.707C>T p.T236I (on ENST00000315906 / NM_001145400.2; = p.T308I on NM_139174.4) | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV51893791; called by muse, mutect2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- ARHGAP23 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747519450; called by muse, mutect2, varscan2
- ATCAY | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 112/555 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs375699107; called by muse, mutect2, varscan2
- B4GALNT1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs139453491, COSV57541086; called by muse, mutect2, varscan2
- BAZ2A | c.5150A>G p.D1717G | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99464240; called by muse, mutect2
- BEGAIN | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1306583469, COSV62068416; called by muse, mutect2, varscan2
- C10orf71 | c.1733C>A p.A578D | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100110708; called by muse, mutect2
- CBY2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs765472548, COSV60118235; called by muse, mutect2, varscan2
- CNOT3 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs746475797; called by muse, mutect2
- COL5A3 | c.4187C>T p.T1396I | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1241146996; called by muse, mutect2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2
- DGCR8 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707762, COSV61225642; called by muse, mutect2
- EDNRB | c.337C>T p.R113W (on ENST00000377211 / NM_001201397.1; = p.R23W on NM_000115.5) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.459); catalogued as rs769618877; called by muse, mutect2
- EPHA10 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750207231, COSV57625960; called by muse, mutect2, varscan2
- GGT5 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs146114235; called by muse, mutect2
- GREB1 | c.5839C>T p.R1947* | Nonsense Mutation (SNP) | VAF 71/374 reads (19%) | catalogued as rs769237746, COSV52195557; called by muse, mutect2, varscan2
- GRIP2 | c.3412C>T p.R1138W (on ENST00000619221; = p.R1041W on NM_001080423.4) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs370347208; called by muse, mutect2, varscan2
- HAS1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99708646; called by muse, mutect2, varscan2
- KRTAP4-16 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.01); catalogued as rs746748830; called by muse, mutect2
- LBP | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367547608; called by muse, mutect2
- LENEP | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs142005786; called by muse, mutect2, varscan2
- MAU2 | c.1155+3G>A | Splice Region (SNP) | VAF 75/305 reads (25%) | catalogued as rs751386140; called by muse, mutect2, varscan2
- MYO18B | c.6121C>T p.R2041W | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769227905, COSV59132360; called by muse, mutect2, varscan2
- NELL1 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54299681; called by muse, mutect2
- NYX | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1165773644; called by muse, mutect2, varscan2
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 35/140 reads (25%) | catalogued as rs745433880, COSV68770009; called by muse, mutect2, varscan2
- PCDHA9 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV65323372; called by muse, mutect2, varscan2
- PDCD1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 7/159 reads (4%) | catalogued as rs756100729, COSV57690800; called by muse, mutect2
- PGM3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756062467; called by muse, mutect2
- PRAMEF20 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 41/488 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs924762274, COSV57080933; called by muse, mutect2
- RASAL3 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs577646736, COSV100640351, COSV59138148; called by muse, mutect2, varscan2
- SHANK1 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV53245306; called by muse, mutect2, varscan2
- SIGLEC6 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs776836710; called by muse, mutect2, varscan2
- SLC49A4 | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs771618109; called by muse, mutect2, varscan2
- SPTBN4 | c.4165C>T p.R1389C | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1342492304; called by muse, mutect2
- SRCIN1 | c.1427C>T p.A476V (on ENST00000621492; = p.A442V on NM_025248.3) | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1385907476; called by muse, mutect2
- TGM2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 174/804 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755189963; called by muse, mutect2, varscan2
- TTN | c.39925G>A p.D13309N (on ENST00000591111; = p.D5885N on NM_003319.4) | Missense Mutation (SNP) | VAF 50/269 reads (19%) | PolyPhen possibly damaging (0.831); catalogued as rs571524382, COSV60064954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBAL3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs201629154, COSV66814563; called by muse, mutect2, varscan2
- UNC13C | c.4810G>T p.D1604Y | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99513915; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 71/440 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770075484; called by muse, mutect2, varscan2
- ZNF34 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs370110948; called by muse, mutect2, varscan2
- ZXDC | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs764787409, COSV60446187; called by muse, mutect2, varscan2
- ADORA2A | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ANK3 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- APC | c.1674_1677del p.N558Kfs*11 | Frame Shift Del (DEL) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- APEX1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- COL4A5 | c.3455G>A p.G1152D | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL9A3 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 339/734 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COMMD10 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CR1L | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); called by muse, mutect2
- DCHS2 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- DNAH11 | c.5203T>C p.F1735L | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGHD | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 20/610 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV3-15 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 96/1148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- IGSF10 | c.5567G>A p.W1856* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- IGSF11 | c.427C>A p.P143T (on ENST00000393775 / NM_001015887.3; = p.P142T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KANSL1L | c.2496dup p.Y833Ifs*2 | Frame Shift Ins (INS) | VAF 57/267 reads (21%) | called by mutect2, pindel, varscan2
- LPIN2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 70/491 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- LRRTM3 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED16 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NIPAL2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2
- PKHD1L1 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PTPN5 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RXFP2 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SIGLEC1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A15 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBB6 | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- WDR81 | c.4959C>G p.C1653W (on ENST00000409644 / NM_001163809.2; = p.C602W on NM_152348.4) | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF782 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZSCAN4 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY3 | c.1797C>T p.S599= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs780804787; called by muse, mutect2, varscan2
- ARMC9 | c.1812C>T p.D604= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as rs199727070, COSV100589767, COSV63020146; called by muse, mutect2, varscan2
- CDKN2B | c.312G>A p.A104= | Silent (SNP) | VAF 126/862 reads (15%) | catalogued as rs755236254; called by muse, mutect2, varscan2
- CORO1A | c.162C>T p.S54= | Silent (SNP) | VAF 16/327 reads (5%) | catalogued as rs536390638, COSV54631117; called by muse, mutect2
- CUX2 | c.2577C>T p.A859= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- ELFN1 | c.387C>T p.R129= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as rs140278883, COSV70033696, COSV70034978; called by muse, mutect2, varscan2
- FCGBP | c.1974C>T p.P658= | Silent (SNP) | VAF 56/230 reads (24%) | catalogued as rs772376965; called by muse, mutect2, varscan2
- GRM1 | c.3207G>A p.P1069= | Silent (SNP) | VAF 66/308 reads (21%) | catalogued as rs1178387181; called by muse, varscan2
- ITGA3 | c.720G>A p.K240= | Silent (SNP) | VAF 7/198 reads (4%) | called by muse, mutect2
- KCTD13 | c.831A>G p.P277= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- KIF2B | c.720G>A p.S240= | Silent (SNP) | VAF 51/246 reads (21%) | catalogued as rs1331727401; called by muse, mutect2, varscan2
- LRRC20 | c.286C>T p.L96= (on ENST00000355790 / NM_207119.3; = p.L46= on NM_018239.4) | Silent (SNP) | VAF 38/381 reads (10%) | catalogued as rs1460455318; called by muse, mutect2, varscan2
- MALSU1 | c.243A>G p.E81= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- NFATC1 | c.627C>T p.C209= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs541173783; called by muse, mutect2, varscan2
- NLGN4X | c.1299G>A p.P433= | Silent (SNP) | VAF 119/324 reads (37%) | catalogued as rs761743135, COSV52039892; called by muse, mutect2, varscan2
- NUTM1 | c.2340T>C p.D780= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- NYAP2 | c.1485C>T p.Y495= | Silent (SNP) | VAF 28/502 reads (6%) | catalogued as rs1473972377, COSV56006709; called by muse, mutect2
- PTPRS | c.1737C>T p.Y579= | Silent (SNP) | VAF 29/442 reads (7%) | catalogued as rs766784309; called by muse, mutect2
- PXMP4 | c.345G>A p.V115= | Silent (SNP) | VAF 153/312 reads (49%) | catalogued as rs1332454850; called by muse, mutect2, varscan2
- SORL1 | c.1773G>A p.G591= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV52757265; called by muse, mutect2
- SPDYE4 | c.438C>T p.A146= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as rs1291643521; called by muse, mutect2, varscan2
- SYNM | c.3732G>A p.G1244= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- THAP5 | c.348G>A p.K116= (on ENST00000415914 / NM_001130475.3; = p.K74= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1458268292; called by muse, mutect2
- ZC3H4 | c.3465C>T p.N1155= | Silent (SNP) | VAF 40/704 reads (6%) | catalogued as rs375922525; called by muse, mutect2
- ZIC1 | c.1062C>T p.H354= | Silent (SNP) | VAF 48/327 reads (15%) | catalogued as COSV51555596, COSV99291725; called by muse, mutect2, varscan2
- ZNF740 | c.564C>T p.D188= | Silent (SNP) | VAF 71/275 reads (26%) | catalogued as rs371041666; called by muse, mutect2, varscan2
- AC092329.3 | c.-211-622G>A | Intron (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- ACTN2 | c.1840-30C>T | Intron (SNP) | VAF 91/417 reads (22%) | called by muse, mutect2, varscan2
- ADGRG6 | c.1069+46T>C | Intron (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- AOPEP | c.*5-632C>T | Intron (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1631A>T | 3'UTR (SNP) | VAF 32/453 reads (7%) | called by muse, mutect2
- CCSER1 | c.2011-35281C>G | Intron (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- CRTC1 | c.*16C>A | 3'UTR (SNP) | VAF 21/363 reads (6%) | called by muse, mutect2
- FGFR3 | chr4:1807680 A>G | 3'Flank (SNP) | VAF 18/217 reads (8%) | catalogued as rs1165597238; called by muse, mutect2
- FOXP2 | c.1267-1583G>A | Intron (SNP) | VAF 8/68 reads (12%) | catalogued as rs747729448; called by muse, mutect2, varscan2
- MS4A1 | c.-150G>A | 5'UTR (SNP) | VAF 21/81 reads (26%) | catalogued as rs771212311; called by muse, mutect2, varscan2
- SDHA | c.*4G>C | 3'UTR (SNP) | VAF 86/568 reads (15%) | called by muse, varscan2
- SIRT3 | c.*15C>A | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- ST8SIA2 | c.*19C>A | 3'UTR (SNP) | VAF 44/270 reads (16%) | catalogued as rs1294451539; called by muse, mutect2, varscan2
- TAF10 | c.*1455T>G | 3'UTR (SNP) | VAF 132/597 reads (22%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.*123C>T | 3'UTR (SNP) | VAF 15/374 reads (4%) | called by muse, mutect2
